Somatic mutation profile of tumor specimen TCGA-91-6835-01A (aliquot TCGA-91-6835-01A-11D-1855-08) from TCGA case TCGA-91-6835, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 81.8 years (29,887 days).
Specimen TCGA-91-6835-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8168075-6514-433c-ad01-7feb66970972.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-91-6835-11A (Solid Tissue Normal), aliquot TCGA-91-6835-11A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f1e44a3-bf1f-4017-a82f-b27a7d434b33

The open-access MAF lists 79 somatic variants for this specimen: 55 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 21, Nonsense Mutation 4, Frame Shift Del 1, Intron 1, RNA 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 14/118 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2
- AKR1C1 | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376003429; called by muse, mutect2
- AKR7A3 | c.904G>C p.A302P | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.747); catalogued as rs748878779, COSV64389796; called by muse, mutect2
- C2CD3 | c.895A>T p.S299C | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58102168; called by muse, mutect2
- CC2D1B | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV52563239; called by muse, mutect2
- CD1E | c.677T>A p.L226Q | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.494); catalogued as COSV63773231; called by muse, mutect2, varscan2
- CDH10 | c.2128G>A p.V710I | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.684); catalogued as rs560951980, COSV100049621, COSV52598944, COSV52600093; called by muse, mutect2
- CDH6 | c.1403A>G p.Q468R | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.71); catalogued as COSV54079297; called by muse, mutect2, varscan2
- CEP350 | c.7625A>G p.Y2542C | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62610423; called by muse, mutect2
- CEP89 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV59868183; called by muse, mutect2
- CSMD3 | c.4034T>C p.V1345A (on ENST00000297405 / NM_001363185.1; = p.V1241A on NM_052900.3) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.034); catalogued as COSV52334720; called by muse, mutect2, varscan2
- CYP2S1 | c.834+1G>T p.X278_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as COSV59507460; called by muse, mutect2, varscan2
- DCTN1 | c.130G>C p.V44L | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV62621631; called by muse, mutect2
- DST | c.2189G>C p.R730T (on ENST00000361203 / NM_001374722.1; = p.R404T on NM_001723.6) | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV55013187, COSV55026350; called by muse, mutect2, varscan2
- EFCAB6 | c.2696G>T p.G899V | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53069158, COSV53073789; called by muse, mutect2, varscan2
- EIF4A1 | c.877C>G p.H293D | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.144); catalogued as COSV51512516; called by muse, mutect2
- EPS8L3 | c.1399C>T p.R467W (on ENST00000361965 / NM_133181.4; = p.R437W on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs759149795, COSV62608767, COSV62609288; called by muse, mutect2, varscan2
- GSG1L | c.826G>T p.E276* (on ENST00000447459 / NM_001109763.2; = p.E121* on NM_144675.2) | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV66582874; called by muse, mutect2, varscan2
- HEATR4 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100620646; called by muse, mutect2, varscan2
- KDM5A | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66996698; called by muse, mutect2, varscan2
- KIF4B | c.3184G>T p.G1062C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as COSV70531823; called by muse, mutect2, varscan2
- KIR3DL1 | c.716G>A p.S239N | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200064560, COSV58496614; called by muse, mutect2
- KLHL38 | c.926C>A p.T309N | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs1354922694, COSV58089420; called by muse, mutect2, varscan2
- LCA5 | c.1163G>C p.R388T | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as COSV63973286; called by muse, mutect2, varscan2
- LYST | c.10778C>A p.T3593K | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV67714964; called by muse, mutect2
- MINK1 | c.2983G>T p.V995F | Missense Mutation (SNP) | VAF 18/478 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53420396; called by muse, mutect2
- MOCOS | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV54347137; called by muse, mutect2, varscan2
- MUC16 | c.3251C>A p.P1084Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as COSV67448884, COSV67497743; called by muse, mutect2, varscan2
- MYH13 | c.4066G>A p.E1356K | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV52844534; called by muse, mutect2
- OR4C3 | c.545T>G p.L182W | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60590984; called by muse, mutect2, varscan2
- PLIN1 | c.413C>A p.T138N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100261756; called by muse, mutect2, varscan2
- POLR3B | c.1297C>G p.R433G | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57284736, COSV57285243; called by muse, mutect2, varscan2
- PRKCA | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52593366; called by muse, mutect2, varscan2
- PRPS1L1 | c.656T>C p.V219A | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs914131650, COSV72650029; called by muse, mutect2, varscan2
- PSG11 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 34/366 reads (9%) | catalogued as COSV60454915, COSV60458274; called by muse, mutect2
- PZP | c.1225A>T p.S409C | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV54371422; called by muse, mutect2
- RABEPK | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52338612; called by muse, mutect2, varscan2
- RBMS1 | c.163G>T p.G55* | Nonsense Mutation (SNP) | VAF 11/120 reads (9%) | catalogued as COSV62357571; called by muse, mutect2
- RGL2 | c.2011A>G p.T671A | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65842996; called by muse, mutect2
- SETX | c.1543A>C p.T515P | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.543); catalogued as COSV56395832; called by muse, mutect2
- SH3PXD2A | c.1750A>T p.R584W (on ENST00000369774 / NM_001365079.1; = p.R556W on NM_014631.2) | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as COSV100280559; called by muse, mutect2
- SLC27A3 | c.617G>A p.R206H (on ENST00000271857; = p.R78H on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.231); catalogued as rs756258170, COSV55165979; called by muse, mutect2, varscan2
- SLC5A11 | c.877G>T p.V293F | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61743862; called by muse, mutect2, varscan2
- SOS2 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99366904; called by muse, mutect2
- STAT3 | c.545A>G p.Q182R | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV52894302; called by muse, mutect2, varscan2
- TMEM63A | c.1119G>C p.Q373H | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.117); catalogued as COSV64764305; called by muse, mutect2
- UGT2B17 | c.747G>T p.E249D | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.693); catalogued as COSV100497323; called by muse, mutect2
- UGT2B17 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV100497324; called by muse, mutect2
- VPS51 | c.2008A>C p.M670L | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV54209663; called by muse, mutect2, varscan2
- ZCCHC2 | c.2267T>C p.V756A | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.239); catalogued as COSV99502716; called by muse, mutect2
- ZFX | c.1396A>G p.N466D | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV58450110; called by muse, mutect2, varscan2
- ZNF236 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 10/138 reads (7%) | catalogued as COSV53485777; called by muse, mutect2
- ZNF407 | c.5438C>G p.S1813C | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55264505, COSV55272087; called by muse, mutect2
- MYL1 | c.97_98delinsA p.P33Tfs*40 | Frame Shift Del (DEL) | VAF 35/308 reads (11%) | called by pindel, varscan2*
- NBEAL2 | c.6697G>T p.D2233Y | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2
- AL592490.1 | c.597C>T p.I199= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as rs1016172171, COSV69428248; called by muse, mutect2
- CLVS1 | c.505C>T p.L169= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV100370403, COSV57983897; called by muse, mutect2, varscan2
- COX10 | c.1206C>T p.D402= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs992018028, COSV55409408; called by muse, mutect2
- DNAH1 | c.7896G>A p.A2632= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as rs199613124; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPHA6 | c.39G>T p.P13= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV67595640; called by muse, mutect2, varscan2
- IGHV3-49 | c.345T>C p.Y115= | Silent (SNP) | VAF 16/213 reads (8%) | called by muse, mutect2
- ITGA6 | c.1581G>A p.A527= (on ENST00000442250; = p.A488= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/245 reads (11%) | catalogued as rs780596840, COSV51221446; called by muse, mutect2, varscan2
- KRT76 | c.633G>A p.L211= | Silent (SNP) | VAF 9/145 reads (6%) | catalogued as COSV60122270; called by muse, mutect2
- LAMA5 | c.4281C>G p.L1427= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV53373775; called by muse, mutect2, varscan2
- MYO15A | c.7188C>T p.D2396= | Silent (SNP) | VAF 4/67 reads (6%) | catalogued as rs1231276113, COSV52767415; called by muse, mutect2
- NCOR1 | c.7140A>C p.S2380= | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as COSV51998913; called by muse, mutect2
- NF1 | c.1182T>C p.F394= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs786202581, COSV62223480; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR10G2 | c.574C>T p.L192= | Silent (SNP) | VAF 16/149 reads (11%) | catalogued as COSV73390483; called by muse, mutect2, varscan2
- POLD2 | c.381A>T p.I127= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99789161; called by muse, mutect2, varscan2
- RFTN1 | c.957A>G p.L319= | Silent (SNP) | VAF 32/207 reads (15%) | catalogued as COSV61923904; called by muse, mutect2, varscan2
- RXFP1 | c.2061A>T p.P687= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV57057467; called by muse, mutect2, varscan2
- SMPD2 | c.621C>T p.F207= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV57807304; called by muse, mutect2, varscan2
- SPAG5 | c.3267C>T p.L1089= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as COSV56887766; called by muse, mutect2
- SPANXN1 | c.165C>T p.C55= | Silent (SNP) | VAF 14/158 reads (9%) | catalogued as rs782601684, COSV100979463, COSV65122993; called by muse, mutect2
- TBCK | c.2658C>T p.L886= (on ENST00000273980 / NM_001163436.4; = p.L823= on NM_033115.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as rs773566416, COSV56762275; called by muse, mutect2, varscan2
- USP4 | c.1656T>A p.G552= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV55540983; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846409 G>A | 5'Flank (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- HDAC9 | c.2577+47G>T | Intron (SNP) | VAF 10/83 reads (12%) | catalogued as rs1164530241; called by muse, mutect2, varscan2
- MIR147A | n.13A>T | RNA (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
